Somatic mutation profile of tumor specimen C3L-05865-54 (aliquot CPT0449290002) from CPTAC case C3L-05865, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 18.8 years (6,869 days).
Specimen C3L-05865-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5124073-5c04-4707-b1b6-befb5d9823d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05865-50 (Buccal Cell Normal), aliquot CPT0449260002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e685bf9-10b2-4e51-9994-5fc4bf60faf2

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF3R | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796065343, COSV58963463; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KCND3 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs768329696; called by muse, mutect2
- MAGI1 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 28/498 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs750221140; called by muse, mutect2
- PHF23 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs774614310; called by muse, mutect2, varscan2
- SMC1A | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 20/618 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781817340, COSV59128385; called by muse, mutect2
- SON | c.7034-4A>T | Splice Region (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99276736; called by muse, mutect2
- COL4A5 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 15/500 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2
- COL4A6 | c.3355G>A p.V1119I | Missense Mutation (SNP) | VAF 11/278 reads (4%) | SIFT tolerated (0.88); PolyPhen benign (0.02); called by muse, mutect2
- PNLIPRP2 | c.392C>A p.A131E | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.935); called by muse, mutect2
- DCHS2 | n.1534A>G | RNA (SNP) | VAF 25/324 reads (8%) | called by muse, mutect2
